Gene-level copy-number profile of tumor specimen TCGA-66-2754-01A from TCGA case TCGA-66-2754, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.0 years (24,471 days).
Specimen TCGA-66-2754-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.5c4b944d-0237-4a8e-b1a2-db99500b6cf3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2754-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5867d3cf-7686-40d4-9cc1-6fe10fae14f3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,744; copy number 2: 21,110; copy number 3: 28,581; copy number 4: 7,173; copy number 5: 1,201; copy number 6: 2; copy number 7: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2754-01A-01D-0978-01): tumor purity 0.87, ploidy 2.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:114,445,521–114,529,452, 1 gene: ZBTB20-AS5.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:128,405,269–128,564,679, 1 gene, copy number 7 (within-gene range 3–7): LINC00824.
- chr9:121,494,519–121,520,424, 2 genes, copy number 7: RN7SL187P, HMGB1P37.
- chr9:121,574,891–121,576,214, 1 gene, copy number 7: AL357936.1.

Autosomal genes at a single copy (total copy number 1): 1,581. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
